Somatic mutation profile of tumor specimen TCGA-BQ-7055-01A (aliquot TCGA-BQ-7055-01A-11D-1961-08) from TCGA case TCGA-BQ-7055, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 73.2 years (26,749 days).
Specimen TCGA-BQ-7055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eab6b3d4-e348-4590-86a1-22d2421a14a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7055-11A (Solid Tissue Normal), aliquot TCGA-BQ-7055-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/901be7cb-1fe6-4fdd-a439-3508c58174b7

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRY1 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV50491636; called by muse, mutect2, varscan2
- SYT3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs760013880, COSV58899084; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs764601182, COSV51512612; called by muse, mutect2, varscan2
- TTN | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | PolyPhen benign (0.039); catalogued as rs774251119, COSV60338545, COSV60347820; called by muse, mutect2, varscan2
- ZNF304 | c.1820G>A p.R607K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as COSV56586499; called by muse, mutect2, varscan2
- CCDC71 | c.780_781del p.R260Sfs*48 | Frame Shift Del (DEL) | VAF 31/142 reads (22%) | called by pindel, varscan2
- DEFB114 | c.49C>T p.L17= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59038564; called by muse, varscan2
- PYGM | c.789C>T p.Y263= | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV51228335; called by muse, mutect2
